Somatic mutation profile of cancer-model specimen HCM-BROD-0483-C16-85M (3D Organoid, passage 4; aliquot HCM-BROD-0483-C16-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0483-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 50.1 years (18,303 days).
Specimen HCM-BROD-0483-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5824fb87-0983-4aa7-9838-4ffa2b17085b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0483-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0483-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/092eda40-c364-4782-954e-b75aceac062b

The open-access MAF lists 99 somatic variants for this specimen: 78 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 20, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPL10L | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 150/243 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV53558657, COSV53559010, COSV53561078; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 289/289 reads (100%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746536178, COSV62789589; called by muse, mutect2, varscan2
- ADAMTS18 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273944; called by muse, mutect2, varscan2
- ADAMTSL1 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52827230; called by muse, mutect2, varscan2
- ADGRB1 | c.4238C>T p.P1413L | Missense Mutation (SNP) | VAF 77/326 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as rs1251936606; called by muse, mutect2, varscan2
- CCDC114 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 255/488 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372835806; called by muse, mutect2, varscan2
- CD209 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 177/410 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs775646663, COSV52652253; called by muse, mutect2, varscan2
- CDH1 | c.662A>T p.D221V | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55732083, COSV55736188; called by muse, mutect2, varscan2
- CECR2 | c.1684C>T p.R562W (on ENST00000342247 / NM_001290047.2; = p.R379W on NM_001290046.1) | Missense Mutation (SNP) | VAF 163/657 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs768986689, COSV52840831; called by muse, mutect2, varscan2
- CHRNA7 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs1247815669; called by mutect2, varscan2
- CNKSR3 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 236/237 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385793306, COSV101401337, COSV70481215; called by muse, mutect2, varscan2
- CSMD1 | c.7016C>T p.P2339L (on ENST00000520002; = p.P2338L on NM_033225.6) | Missense Mutation (SNP) | VAF 97/357 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs990309909, COSV100147072; called by muse, mutect2, varscan2
- DCC | c.4015A>C p.T1339P | Missense Mutation (SNP) | VAF 314/464 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV71434255, COSV71438899; called by muse, mutect2, varscan2
- FARP1 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1481425116; called by muse, mutect2, varscan2
- GEMIN4 | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 415/415 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0.08); catalogued as rs1365894885; called by muse, mutect2, varscan2
- GLI3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 130/370 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750890677, COSV67889940; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 275/1034 reads (27%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1179286746; called by muse, mutect2, varscan2
- GOLGA8S | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs1188473844; called by mutect2, varscan2
- LEPR | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs150826083, COSV60748909; called by muse, mutect2, varscan2
- NLRP1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 303/304 reads (100%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs199648641, COSV99334640; called by muse, mutect2, varscan2
- NLRP3 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 114/368 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.347); catalogued as rs1131691891, COSV60223742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP4 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 203/829 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs772979970; called by muse, mutect2, varscan2
- NLRX1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 135/408 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs544880461, COSV52708580; called by muse, mutect2, varscan2
- NUP210 | c.2034C>A p.F678L | Missense Mutation (SNP) | VAF 168/317 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54411789; called by muse, mutect2, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- RHBDF2 | c.189G>T p.R63S | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV57421059; called by muse, mutect2, varscan2
- RWDD2A | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 173/574 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as rs372834337, COSV52285428; called by muse, mutect2, varscan2
- RXFP1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314177; called by muse, mutect2, varscan2
- RYR3 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754630934; ClinVar: uncertain significance; called by muse, mutect2
- SCN1A | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57670522; called by muse, mutect2, varscan2
- SGCG | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755404457, COSV54565762; called by muse, mutect2, varscan2
- SH2D3C | c.1664C>T p.P555L (on ENST00000314830 / NM_170600.3; = p.P398L on NM_005489.4) | Missense Mutation (SNP) | VAF 191/545 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs370528837; called by muse, mutect2, varscan2
- SLITRK4 | c.1250A>C p.K417T | Missense Mutation (SNP) | VAF 176/551 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV62023203; called by muse, mutect2, varscan2
- SPNS3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 585/585 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs200782432, COSV100337118; called by muse, mutect2, varscan2
- STAB2 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 127/284 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66342131; called by muse, mutect2, varscan2
- TKTL2 | c.1027A>G p.S343G | Missense Mutation (SNP) | VAF 164/303 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs752923064; called by muse, mutect2, varscan2
- TRIB1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 163/960 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs767050256; called by mutect2, varscan2
- TRPC3 | c.997C>T p.R333W (on ENST00000379645 / NM_001366479.2; = p.R260W on NM_003305.2) | Missense Mutation (SNP) | VAF 107/199 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs200628425, COSV53381860; called by muse, mutect2, varscan2
- XKR3 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 162/348 reads (47%) | catalogued as rs868037229; called by muse, mutect2, varscan2
- ZBTB49 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 187/328 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs759220189, COSV61926372; called by muse, mutect2, varscan2
- ZNF154 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 120/652 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs760946726, COSV101377537; called by muse, mutect2, varscan2
- ADAMTS12 | c.2084T>A p.L695Q | Missense Mutation (SNP) | VAF 135/429 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AKAP4 | c.2030G>T p.C677F | Missense Mutation (SNP) | VAF 216/575 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3 | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 79/394 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CACNA1S | c.5089C>A p.P1697T | Missense Mutation (SNP) | VAF 127/503 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR37 | c.1378A>T p.T460S | Missense Mutation (SNP) | VAF 182/376 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- GPR37L1 | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 178/550 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK2 | c.1784G>A p.C595Y | Missense Mutation (SNP) | VAF 116/403 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HHIPL1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HJURP | c.2227T>A p.L743M | Missense Mutation (SNP) | VAF 122/410 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KIF20B | c.3133C>G p.Q1045E (on ENST00000371728 / NM_001284259.2; = p.Q1005E on NM_016195.4) | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KLHL2 | c.322A>T p.R108W | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KMT2D | c.4340A>G p.D1447G | Missense Mutation (SNP) | VAF 193/404 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA1 | c.1737+1G>T p.X579_splice | Splice Site (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- LIFR | c.2678G>C p.S893T | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2
- MYO16 | c.3841T>G p.F1281V | Missense Mutation (SNP) | VAF 240/620 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.095); called by mutect2, varscan2
- NBR1 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 132/435 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR10X1 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- OR8U1 | c.485T>A p.L162H | Missense Mutation (SNP) | VAF 196/1018 reads (19%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.951); called by muse, varscan2
- PLG | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PRAMEF17 | c.331A>T p.N111Y | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PRB2 | c.825A>T p.Q275H | Missense Mutation (SNP) | VAF 76/507 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- PSMB5 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 134/377 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- RASA4 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 108/745 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASA4B | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 164/685 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPS6KA4 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 179/569 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCAF8 | c.1080_1097del p.N361_I366del | In Frame Del (DEL) | VAF 36/231 reads (16%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 196/551 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STXBP5L | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 139/254 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TAC1 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 147/1629 reads (9%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.953); called by muse, mutect2
- TAF1 | c.667C>T p.R223C (on ENST00000373790 / NM_138923.4; = p.R244C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/317 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TEK | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMOD3 | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPD52L3 | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- UNC79 | c.3733G>A p.E1245K (on ENST00000393151 / NM_001346218.2; = p.E1068K on NM_020818.5) | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZC3H7A | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF135 | c.667T>C p.F223L (on ENST00000313434 / NM_001289401.2; = p.F235L on NM_003436.4) | Missense Mutation (SNP) | VAF 169/746 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, varscan2
- ASTN2 | c.930C>T p.R310= | Silent (SNP) | VAF 512/513 reads (100%) | catalogued as rs750217184, COSV57785126; called by muse, mutect2, varscan2
- ATG13 | c.411C>G p.A137= | Silent (SNP) | VAF 17/442 reads (4%) | called by muse, mutect2
- ATP10D | c.3516A>T p.A1172= | Silent (SNP) | VAF 137/293 reads (47%) | called by muse, mutect2, varscan2
- CCNT2 | c.1233T>A p.T411= | Silent (SNP) | VAF 113/326 reads (35%) | called by muse, mutect2, varscan2
- ENOX2 | c.1287G>A p.R429= (on ENST00000338144 / NM_001382520.1; = p.R400= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 148/453 reads (33%) | catalogued as COSV57657827; called by muse, mutect2, varscan2
- FAM126B | c.471C>T p.L157= | Silent (SNP) | VAF 64/254 reads (25%) | catalogued as rs770288801; called by muse, mutect2, varscan2
- GPKOW | c.111C>T p.D37= | Silent (SNP) | VAF 252/788 reads (32%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4947G>A p.R1649= | Silent (SNP) | VAF 157/693 reads (23%) | called by muse, mutect2, varscan2
- KLHL2 | c.321G>T p.L107= | Silent (SNP) | VAF 102/244 reads (42%) | called by muse, mutect2, varscan2
- OR8A1 | c.648T>G p.S216= | Silent (SNP) | VAF 142/400 reads (36%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.33C>T p.G11= | Silent (SNP) | VAF 116/263 reads (44%) | called by muse, mutect2, varscan2
- PNPO | c.270A>G p.G90= | Silent (SNP) | VAF 81/288 reads (28%) | called by muse, mutect2, varscan2
- PROM2 | c.580C>T p.L194= | Silent (SNP) | VAF 310/490 reads (63%) | called by muse, mutect2, varscan2
- RBMXL3 | c.1872C>T p.Y624= | Silent (SNP) | VAF 298/834 reads (36%) | catalogued as rs193239868; called by muse, mutect2, varscan2
- SLC24A4 | c.1188G>A p.P396= | Silent (SNP) | VAF 152/502 reads (30%) | catalogued as rs754076513; called by muse, mutect2
- TBC1D9B | c.1794C>T p.I598= | Silent (SNP) | VAF 131/272 reads (48%) | catalogued as rs781613172, COSV62281165; called by muse, mutect2, varscan2
- TENM2 | c.450G>A p.S150= | Silent (SNP) | VAF 125/263 reads (48%) | catalogued as rs540230946, COSV72857061; called by muse, mutect2, varscan2
- TG | c.2223G>A p.T741= | Silent (SNP) | VAF 168/762 reads (22%) | catalogued as rs779145179, COSV99603224; called by muse, mutect2
- TRIM64B | c.1215A>C p.R405= | Silent (SNP) | VAF 148/1107 reads (13%) | catalogued as rs202169525; called by muse, mutect2, varscan2
- ZNF467 | c.1005C>A p.S335= | Silent (SNP) | VAF 463/464 reads (100%) | called by muse, mutect2, varscan2
- SLC6A1 | c.*652C>T | 3'UTR (SNP) | VAF 149/260 reads (57%) | catalogued as rs1015433669; called by muse, mutect2, varscan2
